Somatic mutation profile of tumor specimen TCGA-BC-A10X-01A (aliquot TCGA-BC-A10X-01A-11D-A12Z-10) from TCGA case TCGA-BC-A10X, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 52.4 years (19,140 days).
Specimen TCGA-BC-A10X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b566b7d-7d3f-4b17-b608-b7ed20e5ed94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A10X-11A (Solid Tissue Normal), aliquot TCGA-BC-A10X-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e847121b-a686-4963-bac3-57ead7b47c1a

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TMEM94 | c.1675T>C p.S559P | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58592671; called by muse, mutect2
- BBS9 | c.180A>G p.G60= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV54154848; called by mutect2, varscan2
- SUN3 | c.66C>T p.S22= | Silent (SNP) | VAF 5/106 reads (5%) | catalogued as COSV99814205; called by muse, mutect2
- TRPA1 | c.1416G>A p.T472= | Silent (SNP) | VAF 32/627 reads (5%) | catalogued as rs555738685, COSV100084112; called by muse, mutect2
- TTBK1 | c.741G>A p.Q247= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV52487812; called by muse, mutect2, varscan2
